Somatic mutation profile of tumor specimen BA3084D (aliquot aq-BA3084D) from BEATAML1.0 case 2694, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.6 years (8,248 days).
Specimen BA3084D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 040323a0-005d-491c-ab1f-57071a52b3a7.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3404D (Solid Tissue Normal), aliquot aq-BA3404D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30505b81-5dd7-42f4-8ebe-03f0bb7ba271

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 50/183 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STAG2 | c.2266-2A>G p.X756_splice | Splice Site (SNP) | VAF 74/94 reads (79%) | catalogued as COSV54354407; called by muse, mutect2, varscan2
- AHNAK2 | c.4088G>A p.S1363N | Missense Mutation (SNP) | VAF 59/307 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ASXL3 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 20/259 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- DNM2 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FSIP2 | c.19540G>A p.E6514K | Missense Mutation (SNP) | VAF 37/416 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2
- FASN | c.7122G>A p.Q2374= | Silent (SNP) | VAF 59/127 reads (46%) | called by muse, mutect2, varscan2
- KMT2C | c.5901A>G p.P1967= | Silent (SNP) | VAF 237/522 reads (45%) | called by muse, mutect2, varscan2
- KRT37 | c.954G>A p.S318= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as rs770826377, COSV56659802; called by muse, mutect2, varscan2
